Somatic mutation profile of cancer-model specimen HCM-BROD-0332-C43-85M (Adherent Cell Line, passage 12; aliquot HCM-BROD-0332-C43-85M-01D-A78T-36), derived from the metastatic tumor of HCMI case HCM-BROD-0332-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 45.0 years (16,451 days).
Specimen HCM-BROD-0332-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 12.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6792d35-b279-4312-8822-a083e10d4180.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0332-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0332-C43-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4678b63c-1678-4147-a217-73785fe7fea6

The open-access MAF lists 756 somatic variants for this specimen: 436 protein-altering or splice-affecting, 237 silent, 83 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 382, Silent 237, Intron 43, Nonsense Mutation 34, 3'UTR 14, 5'UTR 11, Splice Site 10, RNA 7, 5'Flank 6, Splice Region 6, Frame Shift Del 2, 3'Flank 2.

Variants (750 of 756; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 255/484 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRCA2 | c.6908C>T p.S2303F | Missense Mutation (SNP) | VAF 83/191 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.632); catalogued as rs1239798218, COSV66451764, COSV99061584; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL7A1 | c.8245G>A p.G2749R | Missense Mutation (SNP) | VAF 273/588 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912853, CM960417; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1909C>T p.Q637* | Nonsense Mutation (SNP) | VAF 131/131 reads (100%) | catalogued as rs587778833, CM011478, COSV57300672; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.96+2T>G p.X32_splice | Splice Site (SNP) | VAF 346/350 reads (99%) | hotspot (GDC flag); catalogued as COSV53738354; called by muse, varscan2
- AACS | c.1879C>T p.P627S | Missense Mutation (SNP) | VAF 100/360 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs770034698; called by muse, mutect2, varscan2
- ABCC3 | c.4133G>A p.G1378E | Missense Mutation (SNP) | VAF 239/239 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs760201402, COSV53327253; called by muse, mutect2, varscan2
- ACOD1 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 65/65 reads (100%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.615); catalogued as rs1326221232; called by muse, mutect2, varscan2
- ACSM4 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 105/324 reads (32%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.943); catalogued as rs770414864, COSV68066953, COSV68069354; called by muse, mutect2, varscan2
- ADAM18 | c.429G>A p.M143I | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55850127; called by muse, mutect2, varscan2
- ADAMTS12 | c.737G>A p.R246K | Missense Mutation (SNP) | VAF 67/165 reads (41%) | SIFT tolerated (0.73); PolyPhen benign (0.23); catalogued as rs1474524935; called by muse, mutect2, varscan2
- ADGRV1 | c.15565C>T p.P5189S | Missense Mutation (SNP) | VAF 323/671 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.055); catalogued as rs778146797; called by muse, mutect2, varscan2
- ALMS1 | c.8328G>A p.M2776I | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs775982049, COSV100040998; called by muse, mutect2, varscan2
- ANGPT1 | c.1480C>T p.R494* | Nonsense Mutation (SNP) | VAF 66/157 reads (42%) | catalogued as rs144684252; called by muse, mutect2, varscan2
- ANKRD11 | c.6290C>T p.P2097L | Missense Mutation (SNP) | VAF 156/346 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as COSV56366418; called by muse, mutect2, varscan2
- AP2A2 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 111/186 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59962495; called by muse, mutect2, varscan2
- ARL8A | c.441G>A p.M147I | Missense Mutation (SNP) | VAF 138/327 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99693228; called by muse, mutect2, varscan2
- ARMH1 | c.60G>A p.W20* | Nonsense Mutation (SNP) | VAF 291/638 reads (46%) | catalogued as rs1424359261; called by muse, mutect2, varscan2
- ASTN1 | c.2891C>T p.T964I | Missense Mutation (SNP) | VAF 169/394 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV62503054; called by muse, mutect2, varscan2
- ASTN1 | c.471G>A p.M157I | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as rs138594470, COSV56079735; called by muse, mutect2, varscan2
- ATP13A2 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 481/1045 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.155); catalogued as COSV58702685; called by muse, mutect2, varscan2
- ATP6AP1 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 242/243 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs781827825, COSV62340876; called by muse, mutect2, varscan2
- ATP8B4 | c.3078G>A p.W1026* | Nonsense Mutation (SNP) | VAF 81/81 reads (100%) | catalogued as COSV52716790; called by muse, mutect2, varscan2
- B4GALNT3 | c.707+7G>A | Splice Region (SNP) | VAF 134/423 reads (32%) | catalogued as rs553111236; called by muse, mutect2, varscan2
- BCL11A | c.2355G>A p.M785I (on ENST00000335712 / NM_001365609.1; = p.M819I on NM_022893.4) | Missense Mutation (SNP) | VAF 72/130 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as rs1485196223, COSV59635122; called by muse, mutect2
- BIRC6 | c.11659C>G p.Q3887E | Missense Mutation (SNP) | VAF 35/35 reads (100%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.832); catalogued as rs768130166; called by muse, mutect2, varscan2
- BPIFB6 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 137/261 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.231); catalogued as COSV100848481; called by mutect2, varscan2
- BTN2A2 | c.1117G>A p.G373R | Missense Mutation (SNP) | VAF 280/605 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61857007; called by muse, mutect2, varscan2
- C19orf73 | c.186C>A p.F62L | Missense Mutation (SNP) | VAF 166/356 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55521249; called by muse, mutect2, varscan2
- C1orf185 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 81/179 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs925923164, COSV65624933, COSV65625240; called by muse, mutect2, varscan2
- C3orf56 | c.347G>A p.G116E | Missense Mutation (SNP) | VAF 76/134 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.658); catalogued as COSV101228925, COSV67756148; called by muse, mutect2, varscan2
- C6orf118 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 179/181 reads (99%) | SIFT tolerated (0.66); PolyPhen benign (0.055); catalogued as rs1189765141; called by muse, mutect2, varscan2
- C9orf57 | c.359G>A p.W120* (on ENST00000377024 / NM_001371610.1; = p.W98* on NM_001128618.2) | Nonsense Mutation (SNP) | VAF 44/131 reads (34%) | catalogued as rs1270917177; called by muse, varscan2
- CACNA1A | c.1829C>T p.S610F | Missense Mutation (SNP) | VAF 59/59 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64209446; called by muse, mutect2, varscan2
- CACNA2D3 | c.3161C>T p.S1054F | Missense Mutation (SNP) | VAF 123/242 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV55535830; called by muse, mutect2, varscan2
- CADM2 | c.883C>T p.R295* (on ENST00000407528 / NM_001167674.2; = p.R297* on NM_153184.4) | Nonsense Mutation (SNP) | VAF 31/91 reads (34%) | catalogued as rs781077819, COSV67361182; called by muse, mutect2, varscan2
- CAMSAP1 | c.3008C>T p.S1003F | Missense Mutation (SNP) | VAF 95/348 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs891237284, COSV100409882; called by muse, mutect2, varscan2
- CARD9 | c.952-8C>T | Splice Region (SNP) | VAF 108/384 reads (28%) | catalogued as rs758654216; called by muse, mutect2, varscan2
- CCDC73 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 69/113 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV58796036; called by muse, mutect2, varscan2
- CCT6A | c.481C>T p.H161Y | Missense Mutation (SNP) | VAF 94/140 reads (67%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs769437110; called by muse, mutect2, varscan2
- CD1C | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 186/403 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as rs145638725, COSV63805710, COSV63806016; called by muse, mutect2, varscan2
- CDK5RAP2 | c.3187C>T p.P1063S | Missense Mutation (SNP) | VAF 172/266 reads (65%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.763); catalogued as rs768235984; called by muse, mutect2, varscan2
- CFHR5 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 173/392 reads (44%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs868484373, COSV56819570; called by muse, mutect2, varscan2
- CHGB | c.575G>A p.G192E | Missense Mutation (SNP) | VAF 149/233 reads (64%) | SIFT tolerated (0.19); PolyPhen benign (0.04); catalogued as rs771095464; called by muse, mutect2, varscan2
- CMYA5 | c.2941C>T p.P981S | Missense Mutation (SNP) | VAF 91/224 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs555725822; called by muse, mutect2, varscan2
- CNOT6 | c.1003C>T p.R335W | Missense Mutation (SNP) | VAF 49/79 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs769929322, COSV56159636; called by muse, varscan2
- COL5A1 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 223/742 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV65668083; called by muse, mutect2, varscan2
- CR1 | c.4105C>T p.R1369C | Missense Mutation (SNP) | VAF 205/491 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs753192761, COSV65460643; called by muse, mutect2, varscan2
- CSMD3 | c.1310G>A p.R437K | Missense Mutation (SNP) | VAF 72/178 reads (40%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.815); catalogued as rs566426423, COSV52109016, COSV52145907; called by muse, mutect2, varscan2
- DAOA | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 84/148 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV61601631; called by muse, mutect2
- DCC | c.2482C>T p.P828S | Missense Mutation (SNP) | VAF 210/211 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.076); catalogued as rs1453579906, COSV59091351; called by muse, mutect2, varscan2
- DDO | c.557G>A p.G186E (on ENST00000368924 / NM_001368172.1; = p.G127E on NM_004032.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 97/98 reads (99%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs1296332839; called by muse, mutect2, varscan2
- DENND5B | c.465G>A p.M155I | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV60906460; called by muse, mutect2, varscan2
- DGKZ | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 88/409 reads (22%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.091); catalogued as rs1389919813; called by muse, mutect2, varscan2
- DIAPH3 | c.1343G>A p.R448Q (on ENST00000400324 / NM_001042517.2; = p.R185Q on NM_030932.3) | Missense Mutation (SNP) | VAF 60/60 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs145827856, COSV57369405; called by muse, mutect2, varscan2
- DMKN | c.1351C>T p.P451S | Missense Mutation (SNP) | VAF 163/367 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.303); catalogued as rs766879863, COSV60090809; called by muse, mutect2, varscan2
- DNAH1 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 220/413 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as COSV70226876; called by muse, mutect2, varscan2
- DNAH5 | c.13774C>T p.R4592* | Nonsense Mutation (SNP) | VAF 306/642 reads (48%) | catalogued as rs758112779, COSV54210253, COSV54253592, COSV99455552; called by muse, mutect2, varscan2
- DNHD1 | c.9664G>A p.E3222K | Missense Mutation (SNP) | VAF 246/797 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as rs1564822316, COSV54441564; called by muse, mutect2, varscan2
- EIF3I | c.732G>A p.V244= | Splice Region (SNP) | VAF 120/234 reads (51%) | catalogued as rs1391444547; called by muse, mutect2, varscan2
- ELOA2 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 160/160 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as rs1047894639; called by muse, mutect2, varscan2
- ESPNL | c.1193C>T p.T398I | Missense Mutation (SNP) | VAF 29/270 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as COSV58035687; called by muse, mutect2, varscan2
- EYS | c.4402G>A p.D1468N | Missense Mutation (SNP) | VAF 234/234 reads (100%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.031); catalogued as CM1410765; called by muse, mutect2, varscan2
- F5 | c.2717C>T p.P906L | Missense Mutation (SNP) | VAF 119/251 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.034); catalogued as COSV100889098; called by muse, mutect2, varscan2
- FAM135B | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV52725538, COSV52758416; called by muse, mutect2, varscan2
- FAM47A | c.45G>A p.M15I | Missense Mutation (SNP) | VAF 44/44 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as COSV60499846; called by muse, mutect2
- FBXW2 | c.1181C>T p.T394I | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); catalogued as rs1183770232; called by muse, mutect2
- FBXW5 | c.1459G>A p.G487R | Missense Mutation (SNP) | VAF 181/516 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756947005, COSV56402406; called by muse, mutect2, varscan2
- FCRL5 | c.170G>A p.W57* | Nonsense Mutation (SNP) | VAF 234/508 reads (46%) | catalogued as rs747150002; called by muse, mutect2, varscan2
- FCSK | c.1342-7C>T | Splice Region (SNP) | VAF 66/128 reads (52%) | catalogued as COSV99850947; called by muse, mutect2, varscan2
- FGF21 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 368/791 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.205); catalogued as COSV55810418; called by muse, mutect2, varscan2
- FILIP1 | c.3311C>T p.S1104F | Missense Mutation (SNP) | VAF 199/199 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV52740009; called by muse, mutect2, varscan2
- FZD4 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 204/204 reads (100%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.846); catalogued as rs118039628; called by muse, mutect2, varscan2
- GABRG2 | c.1208G>A p.R403Q (on ENST00000361925 / NM_001375343.1; = p.R363Q on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 344/726 reads (47%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.991); catalogued as rs780199000, CM117155, COSV62721593; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLT1D1 | c.917C>T p.P306L (on ENST00000442111 / NM_001366889.1; = p.P226L on NM_144669.3) | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV99896137; called by muse, mutect2, varscan2
- GRB10 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 319/511 reads (62%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV60016611; called by muse, mutect2, varscan2
- GRIN2A | c.3456G>T p.Q1152H | Missense Mutation (SNP) | VAF 96/187 reads (51%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.694); catalogued as COSV58021504; called by muse, mutect2, varscan2
- GRK2 | c.1687G>T p.G563C | Missense Mutation (SNP) | VAF 32/688 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57754004; called by muse, mutect2
- H1-6 | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 164/340 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs759021080; called by muse, mutect2, varscan2
- HMCN1 | c.4057C>T p.L1353F | Missense Mutation (SNP) | VAF 98/226 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54925084; called by muse, mutect2, varscan2
- HS3ST5 | c.121del p.C41Afs*58 | Frame Shift Del (DEL) | VAF 48/120 reads (40%) | catalogued as COSV100451279; called by mutect2, pindel, varscan2
- HYDIN | c.1891G>A p.E631K | Missense Mutation (SNP) | VAF 185/451 reads (41%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as COSV55499059; called by muse, mutect2, varscan2
- IGFN1 | c.3316C>T p.P1106S (on ENST00000295591 / NM_001367841.1; = p.P3563S on NM_001164586.2) | Missense Mutation (SNP) | VAF 96/185 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1185896687, COSV55169297; called by muse, mutect2, varscan2
- INTS8 | c.2501C>T p.S834F | Missense Mutation (SNP) | VAF 54/116 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs753228053; called by muse, mutect2
- ITGAE | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 127/127 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as rs1335812227; called by muse, mutect2, varscan2
- KANK3 | c.1496C>T p.P499L | Missense Mutation (SNP) | VAF 136/136 reads (100%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs747587644; called by muse, mutect2, varscan2
- KCNA1 | c.833G>A p.G278E | Missense Mutation (SNP) | VAF 388/548 reads (71%) | SIFT tolerated (0.17); PolyPhen benign (0.057); catalogued as COSV66839069; called by muse, mutect2, varscan2
- KCNH4 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 266/268 reads (99%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs150022491; called by muse, varscan2
- KIFC2 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 163/398 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs746130674; called by muse, mutect2, varscan2
- KLK15 | c.218G>T p.G73V | Missense Mutation (SNP) | VAF 100/208 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56827325; called by muse, mutect2, varscan2
- KNOP1 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 141/271 reads (52%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.477); catalogued as rs751286698, COSV54929569; called by muse, mutect2, varscan2
- L1TD1 | c.1232C>T p.S411L | Missense Mutation (SNP) | VAF 125/225 reads (56%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.92); catalogued as COSV100776543; called by muse, mutect2, varscan2
- LIMCH1 | c.1625C>T p.S542F | Missense Mutation (SNP) | VAF 164/164 reads (100%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.996); catalogued as rs767564154; called by muse, mutect2
- LMTK3 | c.3860_3871dup p.E1287_E1290dup | In Frame Ins (INS) | VAF 40/91 reads (44%) | catalogued as rs1446016950; called by mutect2, varscan2
- LOXHD1 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 243/244 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV59664063; called by muse, mutect2, varscan2
- LTA4H | c.1334G>T p.W445L | Missense Mutation (SNP) | VAF 78/171 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV99957196; called by muse, mutect2, varscan2
- LTBP2 | c.2552G>A p.G851E | Missense Mutation (SNP) | VAF 216/217 reads (100%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.899); catalogued as rs779396787, COSV56208929; called by muse, mutect2, varscan2
- MAGEA11 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 92/92 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as COSV60756217; called by muse, mutect2, varscan2
- MAL | c.367C>A p.H123N | Missense Mutation (SNP) | VAF 256/436 reads (59%) | SIFT tolerated (0.1); PolyPhen benign (0.229); catalogued as COSV59431059; called by muse, mutect2, varscan2
- MAP3K5 | c.3308G>A p.R1103Q | Missense Mutation (SNP) | VAF 191/192 reads (99%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.978); catalogued as rs78303756, COSV62889847; called by muse, mutect2, varscan2
- MED17 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 163/164 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1346945031; called by muse, mutect2, varscan2
- MICA | c.337C>T p.L113F | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as rs41544623, COSV101319729; called by muse, mutect2, varscan2
- MROH2B | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 54/108 reads (50%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.99); catalogued as COSV68181007; called by muse, mutect2, varscan2
- MUC12 | c.12043C>T p.L4015F (on ENST00000379442; = p.L3872F on NM_001164462.1) | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.03); catalogued as rs1378325006; called by mutect2, varscan2
- MUC5AC | c.988G>A p.G330S | Missense Mutation (SNP) | VAF 168/571 reads (29%) | SIFT tolerated (0.32); catalogued as COSV100650660; called by muse, mutect2, varscan2
- MYRIP | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 116/248 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.067); catalogued as rs1357854257; called by muse, varscan2
- NCKAP5 | c.1984T>C p.S662P | Missense Mutation (SNP) | VAF 24/27 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1374705707; called by muse, mutect2, varscan2
- NFKBIE | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 269/270 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV51487998; called by muse, mutect2, varscan2
- NPAS4 | c.2066G>A p.W689* | Nonsense Mutation (SNP) | VAF 89/307 reads (29%) | catalogued as COSV60648995; called by muse, mutect2, varscan2
- NPHP4 | c.3166C>T p.H1056Y | Missense Mutation (SNP) | VAF 169/309 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as rs747592217; called by muse, mutect2, varscan2
- NTN4 | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 143/217 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs766077128, COSV59223700; called by muse, mutect2, varscan2
- NTRK2 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 133/435 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0.013); catalogued as COSV52859578; called by muse, mutect2, varscan2
- OAS1 | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs751294150, COSV52533991; called by muse, mutect2
- OR4K13 | c.703A>G p.K235E | Missense Mutation (SNP) | VAF 140/372 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs780838493, COSV100237954; called by muse, mutect2, varscan2
- OR5A1 | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 175/265 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV57378318; called by muse, mutect2, varscan2
- OR5AK2 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 99/266 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as COSV58805375; called by muse, mutect2, varscan2
- OR5P2 | c.130C>T p.L44F | Missense Mutation (SNP) | VAF 55/212 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV61491146; called by muse, mutect2, varscan2
- OR6C74 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 56/95 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.417); catalogued as COSV59605973, COSV59607042; called by muse, mutect2, varscan2
- P2RY6 | c.669T>A p.D223E | Missense Mutation (SNP) | VAF 388/594 reads (65%) | SIFT tolerated (1); PolyPhen possibly damaging (0.492); catalogued as rs138018794; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1007C>T p.S336F (on ENST00000259318 / NM_001136562.3; = p.S567F on NM_007203.5) | Missense Mutation (SNP) | VAF 102/319 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1310954099; called by muse, mutect2, varscan2
- PCDHA10 | c.449G>C p.R150P | Missense Mutation (SNP) | VAF 266/518 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); catalogued as COSV56541529; called by muse, mutect2, varscan2
- PCDHA13 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 253/574 reads (44%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.197); catalogued as rs1554175311; called by muse, mutect2, varscan2
- PCLO | c.12281T>A p.F4094Y | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.988); catalogued as COSV100427680; called by muse, mutect2, varscan2
- PGLYRP2 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 117/117 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV52992876, COSV52994190; called by muse, mutect2, varscan2
- PHLDB1 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 270/271 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61879412; called by muse, mutect2, varscan2
- PLEKHG4B | c.1519C>A p.Q507K (on ENST00000283426; = p.Q863K on NM_052909.5) | Missense Mutation (SNP) | VAF 174/359 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs914325270; called by muse, mutect2, varscan2
- PMS1 | c.2611C>T p.R871C | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs143554211; called by muse, mutect2, varscan2
- PODNL1 | c.1126G>A p.G376S | Missense Mutation (SNP) | VAF 261/262 reads (100%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as rs754367853; called by muse, mutect2, varscan2
- POM121L12 | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 234/785 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV68692907; called by muse, mutect2, varscan2
- PPP2R3B | c.1586C>T p.A529V | Missense Mutation (SNP) | VAF 114/231 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.182); catalogued as rs1303007570; called by muse, mutect2
- PREX2 | c.3433C>T p.P1145S | Missense Mutation (SNP) | VAF 84/161 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV55757881; called by muse, mutect2, varscan2
- PTGFR | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 88/182 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV66114419; called by muse, mutect2, varscan2
- PTPN4 | c.1261G>A p.D421N | Missense Mutation (SNP) | VAF 135/163 reads (83%) | SIFT tolerated (0.8); PolyPhen benign (0.19); catalogued as rs1282445576; called by muse, mutect2, varscan2
- REM2 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 509/808 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV57465384; called by muse, mutect2, varscan2
- REV1 | c.1547+2T>C p.X516_splice | Splice Site (SNP) | VAF 44/49 reads (90%) | catalogued as COSV51488403; called by muse, mutect2, varscan2
- RFXAP | c.287C>A p.S96* | Nonsense Mutation (SNP) | VAF 92/92 reads (100%) | catalogued as rs749368415; called by muse, mutect2, varscan2
- RIMKLB | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 207/342 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV55236755; called by muse, mutect2, varscan2
- ROR2 | c.2381C>T p.P794L | Missense Mutation (SNP) | VAF 115/189 reads (61%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs374141378; called by muse, mutect2, varscan2
- ROS1 | c.191G>A p.W64* | Nonsense Mutation (SNP) | VAF 71/72 reads (99%) | catalogued as rs1219188453; called by muse, mutect2, varscan2
- RP1 | c.2416G>A p.E806K | Missense Mutation (SNP) | VAF 116/239 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV55113090; called by muse, mutect2, varscan2
- RP1 | c.5959G>A p.D1987N | Missense Mutation (SNP) | VAF 61/132 reads (46%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as COSV55121191, COSV55123715; called by muse, mutect2, varscan2
- SECISBP2 | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 100/358 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100368874; called by muse, mutect2, varscan2
- SELENOS | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 44/110 reads (40%) | catalogued as rs755796494; called by muse, mutect2, varscan2
- SENP7 | c.1265C>T p.P422L | Missense Mutation (SNP) | VAF 58/109 reads (53%) | SIFT tolerated (0.24); PolyPhen benign (0.084); catalogued as COSV58609832; called by muse, mutect2, varscan2
- SERPINA7 | c.392G>A p.G131E | Missense Mutation (SNP) | VAF 178/179 reads (99%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs148370308, COSV59666422; called by muse, mutect2, varscan2
- SF3B3 | c.2113C>T p.R705* | Nonsense Mutation (SNP) | VAF 161/312 reads (52%) | catalogued as rs753373552; called by muse, mutect2, varscan2
- SFTPA2 | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 243/346 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64882638; called by muse, mutect2, varscan2
- SGPP1 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 196/197 reads (99%) | SIFT tolerated (0.38); PolyPhen benign (0.017); catalogued as rs1270856977; called by muse, mutect2, varscan2
- SIRPD | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 98/298 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as rs760681080; called by muse, varscan2
- SLCO1B3 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 127/189 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53934561; called by muse, mutect2, varscan2
- SORBS2 | c.1883C>T p.S628F | Missense Mutation (SNP) | VAF 557/559 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53016075; called by muse, mutect2, varscan2
- SPOCK1 | c.774G>A p.M258I | Missense Mutation (SNP) | VAF 68/160 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as rs267600350, COSV56458405; called by muse, mutect2, varscan2
- STAC | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 180/327 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56212444; called by muse, mutect2, varscan2
- STARD8 | c.2989G>A p.G997R | Missense Mutation (SNP) | VAF 253/253 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52934299; called by muse, mutect2, varscan2
- SYCP2 | c.430A>G p.K144E | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV100698038; called by muse, mutect2, varscan2
- SYT1 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs138582600, COSV54034805; called by muse, varscan2
- TAFA1 | c.343G>A p.G115R | Missense Mutation (SNP) | VAF 96/244 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72040239; called by muse, varscan2
- TAOK3 | c.1801C>T p.L601F | Missense Mutation (SNP) | VAF 185/548 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs935206860, COSV66824835; called by muse, mutect2, varscan2
- TARBP1 | c.948G>A p.W316* | Nonsense Mutation (SNP) | VAF 53/155 reads (34%) | catalogued as rs767733620; called by muse, mutect2, varscan2
- TBC1D17 | c.646C>T p.L216F | Missense Mutation (SNP) | VAF 196/394 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs1209050497; called by muse, mutect2, varscan2
- TCF7L1 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 67/191 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.265); catalogued as COSV56399618; called by muse, mutect2, varscan2
- TCIRG1 | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 641/970 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs746227782, COSV99693742; called by muse, mutect2, varscan2
- THSD7B | c.1175G>A p.G392E | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.041); catalogued as rs758308510, COSV55683904, COSV55712725; called by muse, mutect2, varscan2
- TICAM2 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 84/196 reads (43%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.204); catalogued as rs767481611, COSV56694841; called by muse, mutect2, varscan2
- TM7SF2 | c.1052A>G p.Y351C | Missense Mutation (SNP) | VAF 104/341 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1047877919; called by muse, mutect2, varscan2
- TMEFF2 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs752891854; called by muse, mutect2, varscan2
- TMEM174 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 64/116 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs145426839, COSV57114237; called by muse, varscan2
- TMEM201 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 223/528 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV100440587; called by muse, mutect2, varscan2
- TMEM88B | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 43/74 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs911501551; called by muse, mutect2, varscan2
- TNIK | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 330/701 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1156310610, COSV52684041; called by muse, mutect2, varscan2
- TPRX1 | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 130/294 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.736); catalogued as rs757971825; called by muse, mutect2, varscan2
- TRAIP | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 98/231 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs866810011, COSV58917462; called by muse, mutect2, varscan2
- TRMU | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 191/192 reads (99%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51990700; called by muse, mutect2, varscan2
- TTLL9 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 133/307 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.055); catalogued as COSV60592033; called by muse, mutect2, varscan2
- TTN | c.65752G>A p.D21918N (on ENST00000591111; = p.D14494N on NM_003319.4) | Missense Mutation (SNP) | VAF 8/64 reads (13%) | PolyPhen probably damaging (0.996); catalogued as rs777257261, COSV60013867; called by muse, mutect2
- UBN1 | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 236/633 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as rs1268432141, COSV52166899, COSV52171247; called by muse, mutect2, varscan2
- UNC13C | c.4403G>A p.R1468Q | Missense Mutation (SNP) | VAF 102/103 reads (99%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs202079449, COSV52855454; called by muse, mutect2, varscan2
- VCL | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 372/373 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM103197; called by muse, mutect2, varscan2
- VPS13D | c.6515C>T p.P2172L | Missense Mutation (SNP) | VAF 213/439 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as rs1051244524, COSV50651726; called by muse, mutect2, varscan2
- VWA3B | c.2950G>A p.E984K | Missense Mutation (SNP) | VAF 158/318 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs760972453; called by muse, mutect2, varscan2
- WDR46 | c.55C>T p.Q19* | Nonsense Mutation (SNP) | VAF 102/206 reads (50%) | catalogued as rs775067332; called by muse, mutect2, varscan2
- YBX1 | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 55/122 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.042); catalogued as rs1282831274, COSV58438419; called by muse, mutect2, varscan2
- ZFPM2 | c.2017C>T p.P673S | Missense Mutation (SNP) | VAF 381/816 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs867948316, COSV65875532; called by muse, mutect2, varscan2
- ZIM3 | c.1190G>A p.G397E | Missense Mutation (SNP) | VAF 139/323 reads (43%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); catalogued as COSV54144204; called by muse, mutect2, varscan2
- ZNF385D | c.773G>A p.G258E | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV55749688; called by muse, mutect2, varscan2
- ZNF469 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 113/217 reads (52%) | SIFT tolerated (0.65); PolyPhen benign (0.172); catalogued as COSV71258878; called by muse, mutect2, varscan2
- ZNF611 | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 127/256 reads (50%) | SIFT tolerated (0.74); PolyPhen benign (0.013); catalogued as COSV60542053; called by muse, mutect2, varscan2
- ABCC8 | c.2467G>A p.G823R | Missense Mutation (SNP) | VAF 261/404 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACOD1 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 65/65 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADAMTS18 | c.2441T>C p.F814S | Missense Mutation (SNP) | VAF 379/866 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- AHSG | c.573+6G>A | Splice Region (SNP) | VAF 255/517 reads (49%) | called by muse, mutect2, varscan2
- AK9 | c.4585G>A p.E1529K | Missense Mutation (SNP) | VAF 17/17 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANGPTL5 | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 97/97 reads (100%) | SIFT tolerated (0.14); PolyPhen benign (0.055); called by muse, varscan2
- ANKDD1B | c.1198C>T p.H400Y | Missense Mutation (SNP) | VAF 77/193 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- ANKRD11 | c.7069A>C p.K2357Q | Missense Mutation (SNP) | VAF 178/494 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- ANKRD18A | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 43/203 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- ANKRD62 | c.1577C>T p.S526F | Missense Mutation (SNP) | VAF 30/32 reads (94%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- APC2 | c.5576C>T p.P1859L | Missense Mutation (SNP) | VAF 186/187 reads (99%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- APOBR | c.281G>A p.S94N | Missense Mutation (SNP) | VAF 45/83 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ARL8A | c.441-1G>A p.X147_splice | Splice Site (SNP) | VAF 135/323 reads (42%) | called by muse, mutect2, varscan2
- ARMH1 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 132/285 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP13A5 | c.1634G>A p.G545E | Missense Mutation (SNP) | VAF 169/372 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- BMP6 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 145/322 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BPIFB3 | c.1346C>T p.P449L | Missense Mutation (SNP) | VAF 88/296 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BTK | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 379/380 reads (100%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- CACNA1H | c.2437G>A p.E813K | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CACNB2 | c.1361C>T p.A454V (on ENST00000324631 / NM_201596.3; = p.A399V on NM_000724.4) | Missense Mutation (SNP) | VAF 327/328 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CALU | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 77/193 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CAMSAP1 | c.2193G>A p.W731* | Nonsense Mutation (SNP) | VAF 181/285 reads (64%) | called by muse, mutect2, varscan2
- CCDC130 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 255/256 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- CCDC9B | c.1057C>T p.Q353* | Nonsense Mutation (SNP) | VAF 126/126 reads (100%) | called by muse, mutect2, varscan2
- CD96 | c.956T>C p.I319T (on ENST00000283285 / NM_198196.3; = p.I303T on NM_005816.5) | Missense Mutation (SNP) | VAF 70/160 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CDH11 | c.1472C>T p.P491L | Missense Mutation (SNP) | VAF 63/189 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CDH11 | c.1471C>T p.P491S | Missense Mutation (SNP) | VAF 64/188 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDK19 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 180/182 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CEACAM18 | c.503G>A p.W168* | Nonsense Mutation (SNP) | VAF 210/461 reads (46%) | called by muse, mutect2, varscan2
- CEP63 | c.1759G>A p.D587N | Missense Mutation (SNP) | VAF 91/170 reads (54%) | SIFT tolerated (0.45); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CFAP47 | c.8825C>T p.S2942L | Missense Mutation (SNP) | VAF 80/81 reads (99%) | SIFT tolerated (0.13); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- CFAP65 | c.2208T>A p.Y736* | Nonsense Mutation (SNP) | VAF 44/364 reads (12%) | called by muse, mutect2, varscan2
- CKLF | c.397C>G p.L133V (on ENST00000264001 / NM_016951.4; = p.L48V on NM_016326.3) | Missense Mutation (SNP) | VAF 267/592 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- CLASRP | c.604C>A p.P202T | Missense Mutation (SNP) | VAF 158/388 reads (41%) | SIFT tolerated (0.09); called by muse, mutect2
- CLCNKA | c.853T>A p.F285I | Missense Mutation (SNP) | VAF 388/960 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLCNKB | c.1364G>A p.G455E | Missense Mutation (SNP) | VAF 439/889 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- CLIP2 | c.672del p.V225Cfs*61 | Frame Shift Del (DEL) | VAF 120/200 reads (60%) | called by mutect2, pindel*, varscan2
- CLSTN1 | c.401G>A p.G134E (on ENST00000377298 / NM_001009566.3; = p.G124E on NM_014944.4) | Missense Mutation (SNP) | VAF 62/116 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLVS2 | c.94C>T p.Q32* | Nonsense Mutation (SNP) | VAF 243/244 reads (100%) | called by muse, mutect2, varscan2
- CNTN1 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 64/212 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- CNTRL | c.2272G>A p.A758T | Missense Mutation (SNP) | VAF 100/186 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- COL17A1 | c.587T>C p.V196A | Missense Mutation (SNP) | VAF 392/392 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- COL4A4 | c.2659C>T p.P887S | Missense Mutation (SNP) | VAF 35/298 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- COL7A1 | c.8246G>A p.G2749E | Missense Mutation (SNP) | VAF 277/594 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRELD1 | c.1183G>A p.G395R | Missense Mutation (SNP) | VAF 316/661 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- CRELD1 | c.1184G>A p.G395E | Missense Mutation (SNP) | VAF 314/656 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- CT55 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 162/172 reads (94%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CUZD1 | c.956C>T p.S319F | Missense Mutation (SNP) | VAF 36/36 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- CWC27 | c.1225C>T p.P409S | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2
- DCTN1 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 118/239 reads (49%) | SIFT tolerated (0.4); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- DDX19B | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 123/312 reads (39%) | called by muse, mutect2, varscan2
- DDX23 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 167/642 reads (26%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDX23 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 166/644 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- DENND4B | c.3620C>T p.P1207L | Missense Mutation (SNP) | VAF 120/229 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- DEPDC4 | c.740T>G p.L247W | Missense Mutation (SNP) | VAF 66/103 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DMXL1 | c.9072A>T p.K3024N | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DNAH11 | c.9337-1G>A p.X3113_splice | Splice Site (SNP) | VAF 29/95 reads (31%) | called by muse, mutect2, varscan2
- DNAH12 | c.4184G>A p.G1395E (on ENST00000351747; = p.G1418E on NM_001366028.2) | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH3 | c.6392C>T p.P2131L | Missense Mutation (SNP) | VAF 86/158 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DNAH6 | c.2990C>T p.S997F | Missense Mutation (SNP) | VAF 110/213 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DNAI3 | c.779G>A p.R260K | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- DNAJB5 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 233/815 reads (29%) | called by muse, mutect2, varscan2
- DOCK7 | c.3917G>T p.S1306I (on ENST00000635253 / NM_001367561.1; = p.S1275I on NM_033407.3) | Missense Mutation (SNP) | VAF 144/285 reads (51%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DPF1 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 194/492 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- DRAXIN | c.770G>A p.G257D | Missense Mutation (SNP) | VAF 168/349 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- DYRK3 | c.1078T>G p.C360G | Missense Mutation (SNP) | VAF 150/307 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DYRK3 | c.1658C>T p.S553F | Missense Mutation (SNP) | VAF 146/337 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- EBF2 | c.1519C>T p.P507S | Missense Mutation (SNP) | VAF 86/154 reads (56%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- EIF4G2 | c.1446G>A p.M482I | Missense Mutation (SNP) | VAF 123/204 reads (60%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- ESPNL | c.2761G>A p.D921N | Missense Mutation (SNP) | VAF 539/611 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EXOC6B | c.683G>A p.R228K | Missense Mutation (SNP) | VAF 44/74 reads (59%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- F5 | c.5021G>A p.G1674E | Missense Mutation (SNP) | VAF 193/387 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM118B | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 68/68 reads (100%) | SIFT tolerated (0.12); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- FAM193B | c.752C>A p.P251H | Missense Mutation (SNP) | VAF 179/366 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM193B | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 167/328 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FBXO41 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 516/1250 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- FCRL1 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 251/452 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- FLG2 | c.97C>A p.L33I | Missense Mutation (SNP) | VAF 107/252 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FNDC3A | c.1951G>A p.E651K (on ENST00000492622 / NM_001079673.2; = p.E595K on NM_014923.5) | Missense Mutation (SNP) | VAF 84/84 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- FOXO6 | c.341T>C p.I114T | Missense Mutation (SNP) | VAF 191/388 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FTO | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 208/509 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, varscan2
- FUZ | c.1034-1G>A p.X345_splice | Splice Site (SNP) | VAF 170/397 reads (43%) | called by muse, varscan2
- GALNT6 | c.1363C>T p.Q455* | Nonsense Mutation (SNP) | VAF 106/150 reads (71%) | called by muse, mutect2, varscan2
- GARRE1 | c.1229C>G p.T410R | Missense Mutation (SNP) | VAF 169/353 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GIMD1 | c.455T>G p.I152R | Missense Mutation (SNP) | VAF 179/180 reads (99%) | SIFT deleterious (0.04); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- GLYATL1 | c.786T>A p.F262L (on ENST00000317391 / NM_001354699.1; = p.F293L on NM_080661.4) | Missense Mutation (SNP) | VAF 196/282 reads (70%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- GPATCH8 | c.1154G>A p.G385E | Missense Mutation (SNP) | VAF 151/151 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRM6 | c.974G>A p.G325E | Missense Mutation (SNP) | VAF 385/917 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GSDMC | c.920G>A p.R307K | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- HCN3 | c.1783C>T p.Q595* | Nonsense Mutation (SNP) | VAF 215/495 reads (43%) | called by muse, mutect2, varscan2
- HGF | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 181/285 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HGFAC | c.17G>A p.W6* | Nonsense Mutation (SNP) | VAF 137/137 reads (100%) | called by muse, mutect2, varscan2
- HIBADH | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 50/79 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- HMGXB3 | c.781G>A p.E261K (on ENST00000613459; = p.E15K on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/266 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- HPSE2 | c.320G>A p.G107E | Missense Mutation (SNP) | VAF 419/420 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- HPSE2 | c.319G>A p.G107R | Missense Mutation (SNP) | VAF 421/421 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- IGFBP1 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- IGHV1-3 | c.19A>C p.I7L | Missense Mutation (SNP) | VAF 266/270 reads (99%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- INCENP | c.1472C>T p.P491L | Missense Mutation (SNP) | VAF 72/264 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.251); called by muse, varscan2
- INPP4A | c.467+2T>C p.X156_splice | Splice Site (SNP) | VAF 15/60 reads (25%) | called by muse, mutect2, varscan2
- INTS8 | c.2503T>C p.W835R | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ITGAE | c.247+1G>A p.X83_splice | Splice Site (SNP) | VAF 126/127 reads (99%) | called by muse, mutect2, varscan2
- ITIH2 | c.2389G>A p.A797T | Missense Mutation (SNP) | VAF 105/106 reads (99%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- JPH3 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 111/244 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- KAT6A | c.307A>C p.I103L | Missense Mutation (SNP) | VAF 352/735 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNMB2 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- KCNMB2 | c.152G>A p.G51E | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- KDM5A | c.2615C>T p.S872F | Missense Mutation (SNP) | VAF 77/231 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- KLHDC9 | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 127/245 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KPNA5 | c.1022T>A p.L341* | Nonsense Mutation (SNP) | VAF 116/117 reads (99%) | called by muse, mutect2, varscan2
- KRTAP5-1 | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 137/435 reads (31%) | PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- LEPR | c.3055C>T p.P1019S | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LIMCH1 | c.267T>G p.C89W | Missense Mutation (SNP) | VAF 100/141 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LMF1 | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 237/521 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- LONP1 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 408/408 reads (100%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LPAR4 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 161/161 reads (100%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- LTA4H | c.1335G>A p.W445* | Nonsense Mutation (SNP) | VAF 75/168 reads (45%) | called by muse, varscan2
- MACROD2 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.616); called by muse, varscan2
- MBTD1 | c.616C>T p.L206F | Missense Mutation (SNP) | VAF 132/132 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- MBTPS1 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 178/384 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MED16 | c.667G>A p.G223S | Missense Mutation (SNP) | VAF 575/579 reads (99%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MED19 | c.106G>C p.A36P | Missense Mutation (SNP) | VAF 178/243 reads (73%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MESP2 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 552/1080 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- MEX3A | c.1394G>A p.G465D | Missense Mutation (SNP) | VAF 328/677 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- MKLN1 | c.261T>A p.F87L | Missense Mutation (SNP) | VAF 57/98 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- MMAB | c.645-1G>A p.X215_splice | Splice Site (SNP) | VAF 271/474 reads (57%) | called by muse, mutect2, varscan2
- MUC6 | c.3137C>T p.P1046L | Missense Mutation (SNP) | VAF 165/668 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MUC6 | c.3136C>T p.P1046S | Missense Mutation (SNP) | VAF 163/669 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MYBPC1 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 181/537 reads (34%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MYH2 | c.2809G>A p.E937K | Missense Mutation (SNP) | VAF 253/319 reads (79%) | SIFT deleterious (0.01); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- MYO7A | c.6587C>T p.S2196F | Missense Mutation (SNP) | VAF 167/284 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NDUFB2 | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 216/455 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- NEK10 | c.1727C>T p.T576I | Missense Mutation (SNP) | VAF 50/94 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- NOL8 | c.1348C>T p.P450S | Missense Mutation (SNP) | VAF 83/221 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NTM | c.168-1G>A p.X56_splice | Splice Site (SNP) | VAF 176/176 reads (100%) | called by muse, mutect2
- NUP210 | c.4312G>A p.G1438S | Missense Mutation (SNP) | VAF 230/491 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- NUTM2B | c.1495A>T p.R499W | Missense Mutation (SNP) | VAF 56/189 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- OR1I1 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 207/210 reads (99%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR51G1 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 193/311 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5AK2 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 36/53 reads (68%) | SIFT tolerated (0.22); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- OTUD5 | c.1544C>T p.P515L | Missense Mutation (SNP) | VAF 211/213 reads (99%) | SIFT tolerated (0.11); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- PAGE5 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 133/133 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- PANK4 | c.1631C>T p.S544F | Missense Mutation (SNP) | VAF 230/480 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PATE4 | c.102G>A p.W34* | Nonsense Mutation (SNP) | VAF 106/106 reads (100%) | called by muse, varscan2
- PCDHGB4 | c.814G>A p.G272S | Missense Mutation (SNP) | VAF 154/301 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- PCDHGC5 | c.1159C>T p.L387F | Missense Mutation (SNP) | VAF 220/467 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PCNX1 | c.5668G>C p.V1890L | Missense Mutation (SNP) | VAF 226/227 reads (100%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCSK1 | c.1082C>T p.T361I | Missense Mutation (SNP) | VAF 223/518 reads (43%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- PDE1C | c.908_916del p.S303_Y306delinsN | In Frame Del (DEL) | VAF 36/221 reads (16%) | called by mutect2, pindel, varscan2
- PDZRN3 | c.2239C>T p.P747S | Missense Mutation (SNP) | VAF 247/512 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PECR | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- PIEZO2 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 74/76 reads (97%) | SIFT tolerated (0.54); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- PKLR | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 624/1274 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- PKN1 | c.1102C>T p.L368F | Missense Mutation (SNP) | VAF 166/167 reads (99%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- PLCH1 | c.842T>A p.F281Y (on ENST00000340059 / NM_001130960.2; = p.F293Y on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/165 reads (52%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- PORCN | c.877G>A p.E293K (on ENST00000326194 / NM_203475.3; = p.E282K on NM_022825.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 501/502 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POTEB3 | c.1381C>G p.P461A | Missense Mutation (SNP) | VAF 80/216 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- POTEH | c.1456C>T p.P486S | Missense Mutation (SNP) | VAF 141/1120 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PPIE | c.941T>A p.I314N | Missense Mutation (SNP) | VAF 52/93 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PPP1R17 | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 88/127 reads (69%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PRH1 | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 301/576 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); called by muse, varscan2
- PRH2 | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 126/624 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- PRRC2B | c.5856G>A p.Q1952= | Splice Region (SNP) | VAF 128/207 reads (62%) | called by muse, mutect2, varscan2
- PSG11 | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 133/249 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- PSMB11 | c.178G>A p.G60R | Missense Mutation (SNP) | VAF 145/386 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PTER | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 180/180 reads (100%) | SIFT tolerated (0.24); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- PTPN14 | c.548C>T p.T183I | Missense Mutation (SNP) | VAF 154/337 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- PTPRD | c.3961C>G p.L1321V | Missense Mutation (SNP) | VAF 64/234 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RAB11FIP3 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- RAP2B | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 178/428 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBM33 | c.1669C>T p.P557S | Missense Mutation (SNP) | VAF 228/480 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RBM44 | c.548G>A p.G183E (on ENST00000611254; = p.G817E on NM_001080504.2) | Missense Mutation (SNP) | VAF 73/88 reads (83%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RDH8 | c.951A>T p.Q317H (on ENST00000651512; = p.Q297H on NM_015725.4) | Missense Mutation (SNP) | VAF 268/268 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- REN | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 260/615 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- RFNG | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 277/280 reads (99%) | SIFT deleterious (0.01); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- RFPL2 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 261/263 reads (99%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- RGS7 | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 243/535 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- RPS6KA1 | c.1375G>T p.E459* | Nonsense Mutation (SNP) | VAF 163/381 reads (43%) | called by muse, mutect2, varscan2
- RPSA | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 133/310 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- RRP9 | c.503G>T p.C168F | Missense Mutation (SNP) | VAF 152/328 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.17); called by muse, varscan2
- RSPRY1 | c.1153C>T p.L385F | Missense Mutation (SNP) | VAF 73/149 reads (49%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- SCAF1 | c.1601C>T p.S534L | Missense Mutation (SNP) | VAF 204/411 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); called by muse, mutect2
- SCN10A | c.3124C>T p.H1042Y | Missense Mutation (SNP) | VAF 68/156 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, varscan2
- SEC16A | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 225/325 reads (69%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- SEC23B | c.734T>A p.L245H | Missense Mutation (SNP) | VAF 116/306 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SEPTIN2 | c.637T>A p.L213I | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- SETX | c.5297C>T p.S1766F | Missense Mutation (SNP) | VAF 49/206 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- SFMBT1 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 223/460 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SGK1 | c.290A>G p.D97G | Missense Mutation (SNP) | VAF 64/64 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SH2D3A | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 286/287 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- SHQ1 | c.1370C>G p.S457W | Missense Mutation (SNP) | VAF 68/278 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- SIGLEC11 | c.1490A>G p.N497S | Missense Mutation (SNP) | VAF 276/610 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- SLC23A3 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 214/248 reads (86%) | SIFT deleterious (0.04); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- SLC46A2 | c.572C>T p.S191F | Missense Mutation (SNP) | VAF 277/432 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC5A12 | c.1579+2T>C p.X527_splice | Splice Site (SNP) | VAF 40/92 reads (43%) | called by muse, mutect2, varscan2
- SLC5A3 | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 143/144 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLITRK2 | c.505C>T p.L169F | Missense Mutation (SNP) | VAF 179/180 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNRPD3 | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 180/181 reads (99%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SPTLC2 | c.404A>G p.N135S | Missense Mutation (SNP) | VAF 177/178 reads (99%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- SSH1 | c.2774C>T p.S925F | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- SSH2 | c.2884T>C p.F962L | Missense Mutation (SNP) | VAF 115/116 reads (99%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ST6GALNAC4 | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 95/253 reads (38%) | called by muse, mutect2, varscan2
- STEAP4 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 179/287 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- TARBP1 | c.947G>A p.W316* | Nonsense Mutation (SNP) | VAF 53/154 reads (34%) | called by muse, mutect2, varscan2
- TASP1 | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 89/260 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- TBR1 | c.1739C>T p.P580L | Missense Mutation (SNP) | VAF 41/283 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TCAIM | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 71/228 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TCAIM | c.1385C>T p.P462L | Missense Mutation (SNP) | VAF 72/227 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TCF7L1 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 66/192 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- TECRL | c.704T>A p.I235N | Missense Mutation (SNP) | VAF 64/64 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- TEKT3 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 156/156 reads (100%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.779); called by muse, mutect2
- TEKT3 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 156/156 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); called by muse, mutect2
- TEX35 | c.401G>A p.R134K | Missense Mutation (SNP) | VAF 287/591 reads (49%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- THADA | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 60/205 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TMEM44 | c.391C>A p.Q131K | Missense Mutation (SNP) | VAF 222/481 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TMEM89 | c.371G>A p.G124E | Missense Mutation (SNP) | VAF 346/722 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TMPRSS6 | c.1555G>A p.G519R | Missense Mutation (SNP) | VAF 147/148 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- TNRC6B | c.4156G>A p.G1386S (on ENST00000454349 / NM_001162501.2; = p.G1276S on NM_015088.3) | Missense Mutation (SNP) | VAF 259/261 reads (99%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TPCN2 | c.1237C>T p.P413S | Missense Mutation (SNP) | VAF 82/272 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- TRANK1 | c.3421C>T p.H1141Y | Missense Mutation (SNP) | VAF 144/346 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- TRIM32 | c.1807C>T p.P603S | Missense Mutation (SNP) | VAF 171/283 reads (60%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- TRIM48 | c.105G>A p.M35I | Missense Mutation (SNP) | VAF 291/461 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- TRIM77 | c.281G>A p.R94K | Missense Mutation (SNP) | VAF 96/96 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TRRAP | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 50/181 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- TSHZ2 | c.1680G>A p.M560I | Missense Mutation (SNP) | VAF 156/280 reads (56%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TSHZ3 | c.2275G>A p.E759K | Missense Mutation (SNP) | VAF 57/108 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- UBN1 | c.982C>T p.P328S | Missense Mutation (SNP) | VAF 243/644 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- VPS16 | c.439C>T p.L147F | Missense Mutation (SNP) | VAF 164/505 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- VWA5B1 | c.3424G>A p.G1142R (on ENST00000375079; = p.G1137R on NM_001039500.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 434/901 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- WASHC5 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 189/442 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- WDR87 | c.5158G>A p.E1720K | Missense Mutation (SNP) | VAF 185/419 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- WLS | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2
- WNK3 | c.4504G>A p.E1502K | Missense Mutation (SNP) | VAF 97/98 reads (99%) | SIFT tolerated (0.05); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- WNK3 | c.4207C>T p.Q1403* | Nonsense Mutation (SNP) | VAF 122/123 reads (99%) | called by muse, mutect2, varscan2
- WWP2 | c.497G>C p.R166T | Missense Mutation (SNP) | VAF 198/399 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- YIF1A | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 304/456 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- YTHDC1 | c.1927C>T p.P643S (on ENST00000344157 / NM_001031732.4; = p.P625S on NM_133370.4) | Missense Mutation (SNP) | VAF 67/68 reads (99%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ZBTB16 | c.1555A>G p.I519V | Missense Mutation (SNP) | VAF 603/605 reads (100%) | SIFT tolerated (0.55); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ZCCHC14 | c.2210C>T p.S737F (on ENST00000268616; = p.S874F on NM_015144.3) | Missense Mutation (SNP) | VAF 327/627 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, varscan2
- ZIC5 | c.1559C>T p.P520L | Missense Mutation (SNP) | VAF 58/58 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF112 | c.1597G>A p.G533S (on ENST00000337401 / NM_001083335.2; = p.G527S on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 110/269 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- ZNF155 | c.217C>T p.Q73* | Nonsense Mutation (SNP) | VAF 59/158 reads (37%) | called by muse, mutect2, varscan2
- ZNF155 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 66/142 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ZNF184 | c.2147A>C p.H716P | Missense Mutation (SNP) | VAF 72/157 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF354B | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 28/51 reads (55%) | called by muse, mutect2, varscan2
- ZNF431 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 124/269 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ZNF662 | c.1078C>T p.H360Y | Missense Mutation (SNP) | VAF 167/319 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZSCAN23 | c.488A>T p.D163V | Missense Mutation (SNP) | VAF 91/209 reads (44%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZYG11A | c.1126G>A p.V376I | Missense Mutation (SNP) | VAF 148/318 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AACS | c.1878C>T p.I626= | Silent (SNP) | VAF 102/365 reads (28%) | called by muse, mutect2, varscan2
- ABCA1 | c.264G>A p.G88= | Silent (SNP) | VAF 169/458 reads (37%) | catalogued as rs757447945; called by muse, mutect2, varscan2
- ABCA13 | c.14619G>A p.G4873= | Silent (SNP) | VAF 106/183 reads (58%) | catalogued as COSV101291323, COSV68944934; called by muse, mutect2, varscan2
- AC023055.1 | c.1434C>T p.S478= | Silent (SNP) | VAF 49/171 reads (29%) | catalogued as COSV100278621; called by muse, mutect2, varscan2
- ANKRD55 | c.1296C>T p.I432= | Silent (SNP) | VAF 196/386 reads (51%) | called by muse, mutect2, varscan2
- ANP32D | c.111C>T p.L37= | Silent (SNP) | VAF 27/157 reads (17%) | called by muse, mutect2, varscan2
- APC2 | c.5577C>T p.P1859= | Silent (SNP) | VAF 186/186 reads (100%) | called by muse, mutect2, varscan2
- ARHGAP23 | c.3195G>A p.V1065= | Silent (SNP) | VAF 239/242 reads (99%) | called by muse, mutect2, varscan2
- ARHGEF1 | c.2244G>A p.R748= | Silent (SNP) | VAF 239/466 reads (51%) | called by muse, mutect2, varscan2
- ARHGEF17 | c.82C>T p.L28= | Silent (SNP) | VAF 329/546 reads (60%) | called by muse, mutect2, varscan2
- ARPP21 | c.255G>A p.Q85= | Silent (SNP) | VAF 158/345 reads (46%) | catalogued as COSV99493261; called by muse, mutect2, varscan2
- ASTN1 | c.849G>A p.G283= | Silent (SNP) | VAF 88/198 reads (44%) | called by muse, mutect2, varscan2
- ASXL3 | c.465G>A p.K155= | Silent (SNP) | VAF 97/97 reads (100%) | called by muse, varscan2
- ATP12A | c.2106G>A p.E702= | Silent (SNP) | VAF 153/357 reads (43%) | called by muse, mutect2, varscan2
- ATP8A2 | c.2739C>T p.I913= | Silent (SNP) | VAF 174/370 reads (47%) | catalogued as rs777620731; called by muse, mutect2, varscan2
- BCL7C | c.552G>A p.R184= | Silent (SNP) | VAF 114/255 reads (45%) | called by muse, mutect2, varscan2
- BLM | c.1452G>A p.K484= | Silent (SNP) | VAF 140/354 reads (40%) | catalogued as COSV100757324; called by muse, mutect2, varscan2
- BRINP1 | c.33C>T p.F11= | Silent (SNP) | VAF 167/252 reads (66%) | catalogued as COSV56300484; called by muse, mutect2, varscan2
- BRINP3 | c.522G>A p.L174= | Silent (SNP) | VAF 113/241 reads (47%) | called by muse, mutect2, varscan2
- BTN2A1 | c.1323C>T p.L441= | Silent (SNP) | VAF 286/567 reads (50%) | called by muse, mutect2, varscan2
- BTN3A3 | c.303G>A p.R101= | Silent (SNP) | VAF 358/1022 reads (35%) | catalogued as rs1369464090; called by muse, mutect2
- C1orf198 | c.651C>T p.S217= | Silent (SNP) | VAF 266/535 reads (50%) | catalogued as rs1558136203; called by muse, mutect2, varscan2
- CADM3 | c.1191C>T p.F397= (on ENST00000368125 / NM_001127173.3; = p.F431= on NM_021189.5) | Silent (SNP) | VAF 34/75 reads (45%) | catalogued as COSV63674091; called by muse, mutect2, varscan2
- CALCB | c.324C>T p.F108= | Silent (SNP) | VAF 128/406 reads (32%) | catalogued as rs145827382; called by muse, mutect2, varscan2
- CALML5 | c.384G>A p.V128= | Silent (SNP) | VAF 255/255 reads (100%) | called by muse, mutect2, varscan2
- CASKIN1 | c.2940G>A p.R980= | Silent (SNP) | VAF 487/1107 reads (44%) | called by muse, mutect2, varscan2
- CCT2 | c.492C>A p.G164= | Silent (SNP) | VAF 67/209 reads (32%) | called by muse, mutect2, varscan2
- CD163L1 | c.4132C>T p.L1378= | Silent (SNP) | VAF 43/162 reads (27%) | called by muse, mutect2, varscan2
- CDH13 | c.237C>T p.G79= | Silent (SNP) | VAF 137/364 reads (38%) | catalogued as rs764913956, COSV51862955; called by muse, mutect2, varscan2
- CDK11A | c.2028C>T p.F676= (on ENST00000378633 / NM_001313896.2; = p.F673= on NM_024011.4) | Silent (SNP) | VAF 201/589 reads (34%) | catalogued as rs572960377; called by muse, mutect2, varscan2
- CDSN | c.549C>T p.Y183= | Silent (SNP) | VAF 564/1130 reads (50%) | called by muse, mutect2, varscan2
- CEACAM19 | c.828A>T p.P276= | Silent (SNP) | VAF 99/202 reads (49%) | called by muse, mutect2, varscan2
- CEP295 | c.6666G>A p.K2222= | Silent (SNP) | VAF 37/37 reads (100%) | called by muse, mutect2, varscan2
- CEP63 | c.1758G>A p.S586= | Silent (SNP) | VAF 88/165 reads (53%) | catalogued as rs751050752, COSV59674256; called by muse, mutect2, varscan2
- CFAP47 | c.9327G>A p.R3109= | Silent (SNP) | VAF 121/121 reads (100%) | called by muse, mutect2, varscan2
- CFAP70 | c.1074G>A p.R358= | Silent (SNP) | VAF 52/53 reads (98%) | called by muse, mutect2, varscan2
- CFTR | c.3099C>T p.F1033= | Silent (SNP) | VAF 142/281 reads (51%) | catalogued as COSV50055114; called by muse, mutect2, varscan2
- CHIT1 | c.36C>T p.V12= | Silent (SNP) | VAF 334/704 reads (47%) | catalogued as COSV55147024; called by muse, mutect2, varscan2
- CILP | c.1155G>T p.V385= | Silent (SNP) | VAF 97/193 reads (50%) | catalogued as COSV56028425; called by muse, mutect2, varscan2
- CLIP1 | c.2481G>A p.G827= (on ENST00000620786 / NM_001247997.1; = p.G816= on NM_002956.2) | Silent (SNP) | VAF 73/126 reads (58%) | catalogued as COSV56809562; called by muse, varscan2
- CLVS1 | c.369C>T p.I123= | Silent (SNP) | VAF 155/355 reads (44%) | catalogued as rs200541190, COSV57971814, COSV57984735; called by muse, mutect2, varscan2
- CNNM1 | c.1270C>T p.L424= | Silent (SNP) | VAF 371/372 reads (100%) | called by muse, mutect2, varscan2
- CNTN1 | c.414C>T p.F138= | Silent (SNP) | VAF 82/358 reads (23%) | called by muse, mutect2, varscan2
- COL8A1 | c.687A>G p.G229= | Silent (SNP) | VAF 106/199 reads (53%) | called by muse, mutect2, varscan2
- COX4I2 | c.456G>T p.V152= | Silent (SNP) | VAF 352/595 reads (59%) | called by muse, mutect2, varscan2
- CST4 | c.318C>T p.F106= | Silent (SNP) | VAF 283/474 reads (60%) | catalogued as COSV54150415; called by muse, mutect2, varscan2
- CYP4F2 | c.1026C>T p.Y342= | Silent (SNP) | VAF 119/360 reads (33%) | called by muse, mutect2
- DCTN6 | c.105C>T p.I35= | Silent (SNP) | VAF 146/288 reads (51%) | catalogued as COSV55318244; called by muse, mutect2, varscan2
- DDAH1 | c.297G>A p.R99= | Silent (SNP) | VAF 140/256 reads (55%) | catalogued as rs772110239; called by muse, mutect2, varscan2
- DDX19B | c.225C>T p.N75= | Silent (SNP) | VAF 124/314 reads (39%) | called by muse, mutect2, varscan2
- DDX60 | c.2499G>A p.T833= | Silent (SNP) | VAF 113/113 reads (100%) | catalogued as rs746559865, COSV67094881; called by muse, mutect2, varscan2
- DLGAP4 | c.546C>T p.A182= | Silent (SNP) | VAF 297/493 reads (60%) | called by muse, mutect2, varscan2
- DMAP1 | c.141C>T p.F47= | Silent (SNP) | VAF 111/277 reads (40%) | called by muse, mutect2, varscan2
- DNAH1 | c.474C>T p.T158= | Silent (SNP) | VAF 314/677 reads (46%) | called by muse, mutect2, varscan2
- DNAH12 | c.7662G>A p.Q2554= (on ENST00000351747; = p.Q3422= on NM_001366028.2) | Silent (SNP) | VAF 208/474 reads (44%) | called by muse, mutect2, varscan2
- DNAH2 | c.7275C>T p.I2425= | Silent (SNP) | VAF 269/271 reads (99%) | catalogued as rs201346992, COSV101209405; called by muse, mutect2, varscan2
- DNAH5 | c.2748A>G p.K916= | Silent (SNP) | VAF 164/358 reads (46%) | catalogued as COSV54240677; called by muse, mutect2, varscan2
- DNHD1 | c.9663G>A p.L3221= | Silent (SNP) | VAF 246/803 reads (31%) | catalogued as rs1460574118; called by muse, mutect2, varscan2
- DOCK8 | c.1704G>A p.Q568= | Silent (SNP) | VAF 121/398 reads (30%) | called by muse, mutect2, varscan2
- DPF1 | c.435G>A p.E145= | Silent (SNP) | VAF 194/486 reads (40%) | called by muse, mutect2, varscan2
- EFL1 | c.2760C>T p.T920= | Silent (SNP) | VAF 176/302 reads (58%) | called by muse, mutect2, varscan2
- EIF4G1 | c.4290G>A p.S1430= (on ENST00000346169 / NM_198241.3; = p.S1235= on NM_004953.5) | Silent (SNP) | VAF 509/1042 reads (49%) | catalogued as rs780282864, COSV59991655; called by muse, mutect2, varscan2
- EPG5 | c.6876C>T p.I2292= | Silent (SNP) | VAF 551/552 reads (100%) | called by muse, mutect2, varscan2
- EPHA2 | c.2028C>T p.I676= | Silent (SNP) | VAF 409/883 reads (46%) | catalogued as COSV64454831; called by muse, mutect2, varscan2
- EPO | c.309G>A p.R103= | Silent (SNP) | VAF 183/306 reads (60%) | called by muse, mutect2, varscan2
- ERP27 | c.345A>G p.E115= | Silent (SNP) | VAF 113/186 reads (61%) | called by muse, mutect2, varscan2
- ESPNL | c.2760G>A p.E920= | Silent (SNP) | VAF 536/607 reads (88%) | called by muse, mutect2, varscan2
- F5 | c.2718C>T p.P906= | Silent (SNP) | VAF 118/254 reads (46%) | called by muse, mutect2, varscan2
- FBXL5 | c.6G>C p.A2= | Silent (SNP) | VAF 207/207 reads (100%) | called by muse, mutect2, varscan2
- FCRL3 | c.1803G>A p.R601= | Silent (SNP) | VAF 247/503 reads (49%) | catalogued as COSV63844854; called by muse, mutect2, varscan2
- FGR | c.717G>A p.A239= | Silent (SNP) | VAF 172/286 reads (60%) | called by muse, mutect2, varscan2
- FHOD1 | c.1023C>T p.I341= | Silent (SNP) | VAF 108/208 reads (52%) | called by muse, mutect2, varscan2
- FREM3 | c.4497C>T p.V1499= | Silent (SNP) | VAF 167/167 reads (100%) | called by muse, mutect2, varscan2
- FRMPD4 | c.51G>A p.T17= | Silent (SNP) | VAF 211/212 reads (100%) | catalogued as rs753155651, COSV66213341, COSV66213803; called by muse, mutect2, varscan2
- FTO | c.1284G>A p.V428= | Silent (SNP) | VAF 219/518 reads (42%) | called by muse, mutect2, varscan2
- FYB1 | c.534G>A p.G178= | Silent (SNP) | VAF 261/600 reads (44%) | catalogued as COSV60954096; called by muse, mutect2, varscan2
- GJA4 | c.255C>T p.V85= | Silent (SNP) | VAF 362/748 reads (48%) | called by muse, mutect2, varscan2
- GOLGB1 | c.6798C>T p.S2266= | Silent (SNP) | VAF 40/68 reads (59%) | called by muse, mutect2, varscan2
- GPR132 | c.516C>T p.I172= | Silent (SNP) | VAF 293/294 reads (100%) | catalogued as rs201333523; called by muse, mutect2, varscan2
- GRM6 | c.975G>A p.G325= | Silent (SNP) | VAF 385/920 reads (42%) | catalogued as rs528831135; called by muse, mutect2, varscan2
- GRM8 | c.1575G>A p.R525= | Silent (SNP) | VAF 290/485 reads (60%) | catalogued as COSV58846241; called by muse, mutect2, varscan2
- GUCY2F | c.2727G>A p.L909= | Silent (SNP) | VAF 169/169 reads (100%) | called by muse, mutect2, varscan2
- HAUS5 | c.951C>T p.V317= | Silent (SNP) | VAF 55/135 reads (41%) | catalogued as rs1265639748, COSV99178314; called by muse, mutect2, varscan2
- HDAC6 | c.498C>T p.V166= | Silent (SNP) | VAF 117/118 reads (99%) | called by muse, mutect2, varscan2
- HOXC6 | c.651C>T p.S217= | Silent (SNP) | VAF 45/126 reads (36%) | catalogued as rs765585868; called by muse, mutect2, varscan2
- HOXC6 | c.652C>T p.L218= | Silent (SNP) | VAF 44/125 reads (35%) | called by muse, mutect2, varscan2
- HSF1 | c.1494C>T p.S498= | Silent (SNP) | VAF 376/780 reads (48%) | catalogued as rs1554846144; called by muse, varscan2
- IDO2 | c.24G>A p.V8= (on ENST00000389060; = p.V21= on NM_194294.2) | Silent (SNP) | VAF 116/276 reads (42%) | called by muse, mutect2, varscan2
- IGHV3-13 | c.168C>T p.V56= | Silent (SNP) | VAF 375/376 reads (100%) | catalogued as rs782218813; called by muse, mutect2, varscan2
- ITIH2 | c.2388G>A p.T796= | Silent (SNP) | VAF 110/110 reads (100%) | catalogued as rs143725175; called by muse, mutect2, varscan2
- IVL | c.957G>A p.Q319= | Silent (SNP) | VAF 418/853 reads (49%) | catalogued as rs370790605; ClinVar: likely benign; called by muse, mutect2, varscan2
- IZUMO3 | c.585C>T p.F195= (on ENST00000543880 / NM_001365008.2; = p.F189= on NM_001271706.1) | Silent (SNP) | VAF 55/79 reads (70%) | called by muse, mutect2, varscan2
- KALRN | c.1776C>T p.T592= | Silent (SNP) | VAF 41/95 reads (43%) | catalogued as COSV53773247; called by muse, mutect2, varscan2
- KCNS3 | c.765G>A p.L255= | Silent (SNP) | VAF 143/143 reads (100%) | catalogued as COSV58408252; called by muse, mutect2, varscan2
- KDM5C | c.3312A>T p.P1104= | Silent (SNP) | VAF 15/490 reads (3%) | called by muse, mutect2
- KRT86 | c.189C>T p.F63= | Silent (SNP) | VAF 265/1077 reads (25%) | catalogued as rs754651481; called by muse, mutect2, varscan2
- KRTAP10-10 | c.747C>T p.S249= | Silent (SNP) | VAF 99/107 reads (93%) | called by muse, mutect2, varscan2
- LAMB2 | c.558C>T p.F186= | Silent (SNP) | VAF 364/705 reads (52%) | called by muse, mutect2, varscan2
- LAMP1 | c.1212C>T p.L404= | Silent (SNP) | VAF 117/304 reads (38%) | catalogued as rs563165417; called by muse, mutect2, varscan2
- LONP1 | c.798C>T p.L266= | Silent (SNP) | VAF 415/415 reads (100%) | catalogued as rs942526080; called by muse, mutect2, varscan2
- LRIT1 | c.1314G>A p.G438= | Silent (SNP) | VAF 417/420 reads (99%) | called by muse, mutect2, varscan2
- LY75 | c.690C>T p.Y230= | Silent (SNP) | VAF 145/158 reads (92%) | called by muse, mutect2, varscan2
- LYN | c.747G>A p.L249= | Silent (SNP) | VAF 137/288 reads (48%) | called by muse, mutect2, varscan2
- MAGI2 | c.1308T>C p.F436= | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as rs536337469; called by muse, mutect2, varscan2
- MAN1A2 | c.168C>T p.F56= | Silent (SNP) | VAF 176/419 reads (42%) | called by muse, mutect2, varscan2
- MAP1B | c.3268T>C p.L1090= | Silent (SNP) | VAF 200/385 reads (52%) | called by muse, mutect2, varscan2
- MAP4 | c.153G>A p.L51= | Silent (SNP) | VAF 195/385 reads (51%) | called by muse, mutect2, varscan2
- MARCHF11 | c.801C>T p.F267= | Silent (SNP) | VAF 112/310 reads (36%) | catalogued as rs1470280202; called by muse, mutect2, varscan2
- MBTD1 | c.615C>T p.A205= | Silent (SNP) | VAF 129/129 reads (100%) | catalogued as rs761039350; called by muse, mutect2, varscan2
- MCF2 | c.1872G>A p.L624= | Silent (SNP) | VAF 40/41 reads (98%) | called by muse, mutect2, varscan2
- MCF2 | c.1266G>A p.R422= | Silent (SNP) | VAF 181/182 reads (99%) | catalogued as COSV58479752, COSV58491104; called by muse, mutect2, varscan2
- MCM2 | c.1002C>T p.F334= | Silent (SNP) | VAF 492/1088 reads (45%) | catalogued as rs376347464, COSV54033010; called by muse, mutect2, varscan2
- MCM3AP | c.2997C>T p.P999= | Silent (SNP) | VAF 47/48 reads (98%) | catalogued as rs753827602; called by muse, mutect2, varscan2
- MCTP2 | c.600G>A p.L200= | Silent (SNP) | VAF 189/432 reads (44%) | called by muse, mutect2, varscan2
- MEX3C | c.270G>A p.E90= | Silent (SNP) | VAF 192/192 reads (100%) | called by muse, mutect2, varscan2
- MGA | c.8910G>A p.K2970= (on ENST00000219905 / NM_001164273.1; = p.K2761= on NM_001080541.2) | Silent (SNP) | VAF 173/174 reads (99%) | called by muse, mutect2, varscan2
- MICA | c.336C>T p.S112= | Silent (SNP) | VAF 59/140 reads (42%) | called by muse, mutect2, varscan2
- MID1IP1 | c.87C>T p.D29= | Silent (SNP) | VAF 65/65 reads (100%) | catalogued as rs372188024, COSV100423625; called by muse, mutect2, varscan2
- MME | c.1353T>C p.F451= | Silent (SNP) | VAF 178/376 reads (47%) | called by muse, mutect2, varscan2
- MMP14 | c.1146C>T p.F382= | Silent (SNP) | VAF 91/215 reads (42%) | catalogued as rs780053954; called by muse, mutect2, varscan2
- MMP23B | c.939G>A p.E313= | Silent (SNP) | VAF 189/763 reads (25%) | catalogued as rs1305236438; called by muse, mutect2, varscan2
- MOSPD3 | c.354G>A p.E118= | Silent (SNP) | VAF 182/636 reads (29%) | catalogued as rs145484365; called by muse, mutect2, varscan2
- MTR | c.3336G>A p.K1112= | Silent (SNP) | VAF 61/1160 reads (5%) | called by muse, mutect2
- MUC16 | c.26049G>A p.G8683= | Silent (SNP) | VAF 84/84 reads (100%) | catalogued as COSV67449976; called by muse, mutect2, varscan2
- MUC16 | c.4737C>T p.A1579= | Silent (SNP) | VAF 155/156 reads (99%) | called by muse, mutect2, varscan2
- MUC5AC | c.987G>A p.R329= | Silent (SNP) | VAF 174/582 reads (30%) | called by muse, mutect2, varscan2
- MYBPC1 | c.42C>G p.A14= | Silent (SNP) | VAF 181/533 reads (34%) | called by muse, mutect2, varscan2
- MYH1 | c.5436G>A p.G1812= | Silent (SNP) | VAF 301/303 reads (99%) | called by muse, mutect2, varscan2
- MYH3 | c.3535C>T p.L1179= | Silent (SNP) | VAF 408/409 reads (100%) | catalogued as rs375904355; called by muse, mutect2, varscan2
- MYO9A | c.732G>A p.G244= | Silent (SNP) | VAF 79/175 reads (45%) | called by muse, mutect2, varscan2
- NAT2 | c.351G>A p.R117= | Silent (SNP) | VAF 64/133 reads (48%) | catalogued as rs879610883, COSV54061398; called by muse, mutect2, varscan2
- NCKAP5L | c.1443C>T p.P481= | Silent (SNP) | VAF 52/83 reads (63%) | called by muse, mutect2, varscan2
- NDUFB2 | c.159C>T p.S53= | Silent (SNP) | VAF 215/455 reads (47%) | catalogued as rs1028629147; called by muse, mutect2, varscan2
- NLRP10 | c.1461G>A p.L487= | Silent (SNP) | VAF 217/334 reads (65%) | called by muse, mutect2, varscan2
- NLRP2 | c.78C>T p.F26= | Silent (SNP) | VAF 476/952 reads (50%) | called by muse, mutect2, varscan2
- NLRP7 | c.1413C>T p.F471= | Silent (SNP) | VAF 258/609 reads (42%) | catalogued as COSV60183884; called by muse, mutect2, varscan2
- NMUR2 | c.1095C>T p.F365= | Silent (SNP) | VAF 316/667 reads (47%) | catalogued as COSV54919567; called by muse, mutect2, varscan2
- NUMA1 | c.972C>T p.S324= | Silent (SNP) | VAF 96/262 reads (37%) | catalogued as COSV100706348; called by muse, mutect2, varscan2
- NUP153 | c.177C>T p.F59= | Silent (SNP) | VAF 130/292 reads (45%) | called by muse, mutect2
- NUP210 | c.4311G>A p.K1437= | Silent (SNP) | VAF 229/483 reads (47%) | called by muse, mutect2, varscan2
- OBSCN | c.21807C>T p.T7269= | Silent (SNP) | VAF 670/1399 reads (48%) | catalogued as rs375871394; called by muse, mutect2, varscan2
- OR11L1 | c.99C>T p.L33= | Silent (SNP) | VAF 214/465 reads (46%) | catalogued as COSV100869483, COSV63314667, COSV63315674; called by muse, mutect2, varscan2
- OR13H1 | c.165C>T p.L55= | Silent (SNP) | VAF 189/189 reads (100%) | called by muse, mutect2, varscan2
- OR1J4 | c.879G>A p.R293= | Silent (SNP) | VAF 93/149 reads (62%) | catalogued as COSV61589852; called by muse, mutect2, varscan2
- OR1Q1 | c.849C>T p.P283= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as COSV52918528; called by muse, mutect2
- OR2F1 | c.477G>A p.Q159= | Silent (SNP) | VAF 177/390 reads (45%) | called by muse, mutect2, varscan2
- OR4X1 | c.747C>T p.F249= | Silent (SNP) | VAF 170/249 reads (68%) | called by muse, mutect2, varscan2
- OR4X2 | c.565C>T p.L189= | Silent (SNP) | VAF 153/445 reads (34%) | called by muse, mutect2, varscan2
- OR51L1 | c.816C>T p.P272= | Silent (SNP) | VAF 123/199 reads (62%) | catalogued as COSV58625937; called by muse, mutect2, varscan2
- OR51S1 | c.159C>T p.I53= | Silent (SNP) | VAF 217/292 reads (74%) | called by muse, mutect2, varscan2
- PATJ | c.4686C>T p.I1562= | Silent (SNP) | VAF 124/227 reads (55%) | catalogued as rs778137687; called by muse, mutect2, varscan2
- PCDHA12 | c.1977G>T p.L659= | Silent (SNP) | VAF 604/1298 reads (47%) | called by muse, mutect2, varscan2
- PDIA2 | c.1542G>T p.P514= | Silent (SNP) | VAF 211/485 reads (44%) | catalogued as rs370503482; called by muse, mutect2, varscan2
- PER3 | c.2490C>T p.S830= | Silent (SNP) | VAF 339/771 reads (44%) | catalogued as rs745794602, COSV100728311; called by muse, mutect2, varscan2
- PIEZO1 | c.7303C>T p.L2435= | Silent (SNP) | VAF 123/282 reads (44%) | called by muse, mutect2, varscan2
- PIGR | c.1923C>T p.V641= | Silent (SNP) | VAF 273/570 reads (48%) | called by muse, mutect2, varscan2
- PLCL2 | c.1200C>T p.L400= (on ENST00000615277 / NM_001144382.2; = p.L274= on NM_015184.5) | Silent (SNP) | VAF 78/169 reads (46%) | called by muse, mutect2, varscan2
- PLD1 | c.2515C>T p.L839= | Silent (SNP) | VAF 153/327 reads (47%) | catalogued as COSV100577605; called by muse, mutect2, varscan2
- PLEC | c.174G>A p.R58= | Silent (SNP) | VAF 756/1479 reads (51%) | called by muse, mutect2, varscan2
- PLG | c.2334T>C p.T778= | Silent (SNP) | VAF 236/270 reads (87%) | called by muse, mutect2, varscan2
- PLSCR3 | c.225C>T p.G75= | Silent (SNP) | VAF 318/319 reads (100%) | catalogued as rs1321298200; called by muse, mutect2, varscan2
- POLQ | c.2085C>T p.A695= | Silent (SNP) | VAF 130/316 reads (41%) | called by muse, mutect2, varscan2
- POM121C | c.600G>A p.R200= | Silent (SNP) | VAF 186/293 reads (63%) | catalogued as rs1554474027; called by muse, mutect2, varscan2
- POU3F2 | c.1110G>A p.E370= | Silent (SNP) | VAF 214/215 reads (100%) | catalogued as COSV60408416, COSV60409659; called by muse, mutect2, varscan2
- PPP1R3A | c.285G>A p.G95= | Silent (SNP) | VAF 110/366 reads (30%) | called by muse, mutect2, varscan2
- PRAMEF8 | c.1002C>T p.F334= | Silent (SNP) | VAF 540/1807 reads (30%) | called by muse, mutect2, varscan2
- PREPL | c.1008T>C p.N336= | Silent (SNP) | VAF 58/119 reads (49%) | catalogued as rs1449313825; called by muse, mutect2, varscan2
- PRKCB | c.1398C>T p.D466= | Silent (SNP) | VAF 98/159 reads (62%) | catalogued as COSV100334196; called by muse, mutect2, varscan2
- PROZ | c.891G>A p.R297= | Silent (SNP) | VAF 182/332 reads (55%) | called by muse, mutect2, varscan2
- PTPRH | c.2175G>A p.R725= | Silent (SNP) | VAF 376/845 reads (44%) | catalogued as COSV54750318; called by muse, mutect2, varscan2
- RAB20 | c.193C>T p.L65= | Silent (SNP) | VAF 101/186 reads (54%) | called by muse, mutect2, varscan2
- RAVER2 | c.228G>T p.L76= | Silent (SNP) | VAF 21/750 reads (3%) | called by muse, mutect2
- RCSD1 | c.135G>A p.R45= | Silent (SNP) | VAF 43/137 reads (31%) | catalogued as rs267598151, COSV63259298; called by muse, mutect2, varscan2
- RECQL | c.1629G>A p.E543= | Silent (SNP) | VAF 20/121 reads (17%) | catalogued as COSV99556429; called by muse, mutect2, varscan2
- RNF123 | c.2937C>T p.F979= | Silent (SNP) | VAF 304/624 reads (49%) | catalogued as rs772267797, COSV100246623; called by muse, mutect2, varscan2
- RRN3 | c.1953C>T p.L651= | Silent (SNP) | VAF 65/116 reads (56%) | called by muse, mutect2, varscan2
- SCAF1 | c.1599C>T p.A533= | Silent (SNP) | VAF 208/418 reads (50%) | catalogued as rs1229060773; called by muse, mutect2
- SCARA5 | c.192G>A p.G64= | Silent (SNP) | VAF 137/347 reads (39%) | called by muse, mutect2, varscan2
- SCN2A | c.1485C>T p.S495= | Silent (SNP) | VAF 157/190 reads (83%) | catalogued as rs756904745; called by muse, mutect2, varscan2
- SEMA4A | c.1935G>A p.Q645= | Silent (SNP) | VAF 202/418 reads (48%) | called by muse, mutect2, varscan2
- SH2D1B | c.33C>G p.T11= | Silent (SNP) | VAF 210/449 reads (47%) | catalogued as rs142252768; called by muse, mutect2, varscan2
- SLC1A5 | c.819C>T p.I273= | Silent (SNP) | VAF 73/148 reads (49%) | called by muse, mutect2, varscan2
- SLC22A25 | c.1242C>T p.F414= | Silent (SNP) | VAF 125/377 reads (33%) | catalogued as COSV60594955; called by muse, mutect2, varscan2
- SLC24A2 | c.1173G>A p.K391= | Silent (SNP) | VAF 187/641 reads (29%) | catalogued as rs1252351737; called by muse, mutect2, varscan2
- SLC25A24 | c.678T>C p.G226= | Silent (SNP) | VAF 73/145 reads (50%) | called by muse, mutect2, varscan2
- SLC46A2 | c.573C>T p.S191= | Silent (SNP) | VAF 281/439 reads (64%) | catalogued as rs200832237; called by muse, mutect2, varscan2
- SLC4A2 | c.1815C>T p.F605= | Silent (SNP) | VAF 287/713 reads (40%) | called by muse, mutect2, varscan2
- SLC6A5 | c.1458C>T p.I486= | Silent (SNP) | VAF 165/569 reads (29%) | catalogued as rs1187324870; called by muse, mutect2, varscan2
- SLC7A10 | c.987G>A p.G329= | Silent (SNP) | VAF 243/498 reads (49%) | called by muse, mutect2, varscan2
- SOCS2 | c.327C>T p.I109= | Silent (SNP) | VAF 43/163 reads (26%) | catalogued as rs745672345; called by muse, mutect2, varscan2
- SPAG8 | c.1224A>G p.Q408= | Silent (SNP) | VAF 142/244 reads (58%) | called by muse, mutect2, varscan2
- SPATA31A1 | c.1209C>T p.L403= | Silent (SNP) | VAF 144/652 reads (22%) | called by muse, mutect2, varscan2
- SPRYD3 | c.129G>A p.Q43= | Silent (SNP) | VAF 116/364 reads (32%) | catalogued as rs755093937; called by muse, varscan2
- SRRM1 | c.2673C>T p.A891= | Silent (SNP) | VAF 106/268 reads (40%) | called by muse, mutect2, varscan2
- ST6GALNAC4 | c.588C>T p.F196= | Silent (SNP) | VAF 99/255 reads (39%) | catalogued as rs757567213, COSV100231403; called by muse, mutect2, varscan2
- STAB1 | c.372G>A p.G124= | Silent (SNP) | VAF 276/616 reads (45%) | called by muse, mutect2, varscan2
- STAB1 | c.5100C>T p.I1700= | Silent (SNP) | VAF 272/702 reads (39%) | catalogued as COSV100401455; called by muse, mutect2, varscan2
- STAB1 | c.5101C>T p.L1701= | Silent (SNP) | VAF 276/703 reads (39%) | called by muse, mutect2, varscan2
- STAT6 | c.129C>T p.V43= | Silent (SNP) | VAF 178/270 reads (66%) | catalogued as rs1290071262, COSV100273343; called by muse, mutect2, varscan2
- SYNE1 | c.8296C>T p.L2766= (on ENST00000367255 / NM_182961.4; = p.L2773= on NM_033071.3) | Silent (SNP) | VAF 344/347 reads (99%) | called by muse, mutect2, varscan2
- SYT12 | c.1020C>T p.A340= | Silent (SNP) | VAF 152/467 reads (33%) | catalogued as rs759542369; called by muse, mutect2, varscan2
- TADA2A | c.1092C>T p.P364= | Silent (SNP) | VAF 151/151 reads (100%) | called by muse, mutect2, varscan2
- TADA3 | c.136C>T p.L46= | Silent (SNP) | VAF 220/485 reads (45%) | called by muse, mutect2, varscan2
- TADA3 | c.135C>T p.T45= | Silent (SNP) | VAF 226/491 reads (46%) | called by muse, mutect2, varscan2
- TAS2R1 | c.429C>T p.F143= | Silent (SNP) | VAF 102/200 reads (51%) | catalogued as COSV66779608; called by muse, mutect2, varscan2
- TBC1D17 | c.645C>T p.F215= | Silent (SNP) | VAF 196/394 reads (50%) | catalogued as rs765380771, COSV55580114; called by muse, mutect2, varscan2
- TBC1D21 | c.324G>A p.L108= | Silent (SNP) | VAF 276/623 reads (44%) | called by muse, mutect2, varscan2
- TDGF1 | c.162G>A p.Q54= | Silent (SNP) | VAF 402/917 reads (44%) | catalogued as COSV56128832; called by muse, mutect2, varscan2
- TGM2 | c.969C>T p.I323= | Silent (SNP) | VAF 192/362 reads (53%) | catalogued as COSV63932276; called by muse, mutect2, varscan2
- TMEM163 | c.498C>T p.S166= | Silent (SNP) | VAF 86/98 reads (88%) | called by muse, mutect2, varscan2
- TMIGD1 | c.501C>T p.S167= | Silent (SNP) | VAF 152/152 reads (100%) | catalogued as rs764684694; called by muse, mutect2, varscan2
- TNIK | c.1053G>A p.R351= | Silent (SNP) | VAF 335/716 reads (47%) | catalogued as rs1452191509; called by muse, mutect2, varscan2
- TPH2 | c.951C>T p.C317= | Silent (SNP) | VAF 105/405 reads (26%) | called by muse, mutect2, varscan2
- TRDV1 | c.201C>T p.F67= | Silent (SNP) | VAF 138/244 reads (57%) | called by muse, mutect2, varscan2
- TRIM62 | c.528C>T p.T176= | Silent (SNP) | VAF 285/578 reads (49%) | called by muse, mutect2, varscan2
- TRPM6 | c.6030G>A p.E2010= | Silent (SNP) | VAF 133/472 reads (28%) | called by muse, mutect2, varscan2
- TRPM8 | c.3000C>T p.F1000= | Silent (SNP) | VAF 139/157 reads (89%) | catalogued as COSV100224467; called by muse, mutect2, varscan2
- TRPV5 | c.534C>T p.I178= | Silent (SNP) | VAF 287/634 reads (45%) | catalogued as rs756706366, COSV54686146; called by muse, mutect2, varscan2
- TTC6 | c.369G>A p.R123= | Silent (SNP) | VAF 271/619 reads (44%) | called by muse, mutect2, varscan2
- TTYH3 | c.451C>T p.L151= | Silent (SNP) | VAF 497/733 reads (68%) | called by muse, mutect2, varscan2
- ULK4 | c.2136C>T p.T712= | Silent (SNP) | VAF 86/171 reads (50%) | called by muse, mutect2, varscan2
- ULK4 | c.723G>A p.P241= | Silent (SNP) | VAF 53/119 reads (45%) | catalogued as rs201612646; called by muse, mutect2, varscan2
- USP17L7 | c.72G>A p.R24= | Silent (SNP) | VAF 443/1827 reads (24%) | catalogued as rs767097322; called by muse, mutect2, varscan2
- USP34 | c.3993C>T p.L1331= | Silent (SNP) | VAF 101/245 reads (41%) | called by muse, mutect2, varscan2
- VPS13B | c.813G>A p.L271= | Silent (SNP) | VAF 43/95 reads (45%) | called by muse, mutect2, varscan2
- VPS13D | c.486T>G p.G162= | Silent (SNP) | VAF 125/294 reads (43%) | called by muse, mutect2, varscan2
- WDR59 | c.831C>T p.T277= | Silent (SNP) | VAF 162/366 reads (44%) | called by muse, mutect2, varscan2
- WLS | c.663G>A p.L221= | Silent (SNP) | VAF 40/82 reads (49%) | called by muse, mutect2
- ZAR1L | c.351C>T p.P117= | Silent (SNP) | VAF 143/274 reads (52%) | called by muse, mutect2, varscan2
- ZCCHC17 | c.57C>T p.F19= | Silent (SNP) | VAF 86/206 reads (42%) | called by muse, varscan2
- ZMYM4 | c.3768T>C p.S1256= | Silent (SNP) | VAF 134/270 reads (50%) | called by muse, mutect2, varscan2
- ZNF473 | c.618G>A p.E206= | Silent (SNP) | VAF 88/179 reads (49%) | called by muse, mutect2, varscan2
- ZNF484 | c.783C>T p.S261= | Silent (SNP) | VAF 56/170 reads (33%) | called by muse, mutect2, varscan2
- ZNF492 | c.1131C>T p.F377= | Silent (SNP) | VAF 28/166 reads (17%) | called by mutect2, varscan2
- ZNF516 | c.2253C>T p.S751= | Silent (SNP) | VAF 314/314 reads (100%) | called by muse, mutect2, varscan2
- ZNF616 | c.1284G>A p.Q428= | Silent (SNP) | VAF 119/237 reads (50%) | called by muse, mutect2, varscan2
- ZNF98 | c.1254C>T p.F418= | Silent (SNP) | VAF 72/294 reads (24%) | catalogued as rs1330425502; called by muse, varscan2
- AAK1 | c.*9723C>T | 3'UTR (SNP) | VAF 229/400 reads (57%) | called by muse, mutect2, varscan2
- ABCC6P1 | n.1159C>T | RNA (SNP) | VAF 445/891 reads (50%) | catalogued as rs767225971; called by muse, mutect2, varscan2
- ABLIM1 | c.1041+2603C>T | Intron (SNP) | VAF 83/83 reads (100%) | called by muse, mutect2, varscan2
- AC107023.1 | n.25+7650G>A | Intron (SNP) | VAF 87/179 reads (49%) | catalogued as rs569504787; called by muse, mutect2, varscan2
- AC107023.1 | n.25+7649G>A | Intron (SNP) | VAF 87/179 reads (49%) | called by muse, mutect2, varscan2
- ACSF3 | c.*339A>G | 3'UTR (SNP) | VAF 249/518 reads (48%) | called by muse, mutect2, varscan2
- AGBL4 | c.1267+72G>A | Intron (SNP) | VAF 98/208 reads (47%) | catalogued as rs1210129933; called by muse, mutect2, varscan2
- APOE | c.-33C>T | 5'UTR (SNP) | VAF 181/409 reads (44%) | catalogued as rs553197505; called by muse, mutect2, varscan2
- ATP11AUN | n.992G>A | RNA (SNP) | VAF 43/91 reads (47%) | called by muse, mutect2, varscan2
- ATP8B1 | c.2097+49G>A | Intron (SNP) | VAF 34/34 reads (100%) | catalogued as COSV99376881; called by muse, mutect2
- BAD | c.*143C>T | 3'UTR (SNP) | VAF 76/108 reads (70%) | catalogued as COSV99657319; called by muse, mutect2, varscan2
- C1S | c.1067-20C>T | Intron (SNP) | VAF 155/566 reads (27%) | called by muse, mutect2, varscan2
- C6orf99 | n.463+3260C>T | Intron (SNP) | VAF 133/134 reads (99%) | called by muse, mutect2, varscan2
- CDC20B | c.126+1977G>A | Intron (SNP) | VAF 162/345 reads (47%) | catalogued as COSV99697380; called by muse, mutect2, varscan2
- CFAP57 | c.1929+10G>A | Intron (SNP) | VAF 168/316 reads (53%) | called by muse, mutect2, varscan2
- CFAP94 | c.89-164G>A | Intron (SNP) | VAF 14/28 reads (50%) | called by muse, mutect2, varscan2
- CHRND | c.*854G>A | 3'UTR (SNP) | VAF 222/252 reads (88%) | called by muse, mutect2, varscan2
- CICP28 | chr7:56811879 G>A | 3'Flank (SNP) | VAF 314/459 reads (68%) | catalogued as rs1554353481; called by muse, mutect2, varscan2
- CLVS1 | c.-152+21C>T | Intron (SNP) | VAF 438/860 reads (51%) | catalogued as rs1373323438; called by muse, mutect2, varscan2
- COL7A1 | c.8226+10C>T | Intron (SNP) | VAF 72/147 reads (49%) | called by muse, mutect2, varscan2
- CPAMD8 | c.5568-1106C>T | Intron (SNP) | VAF 160/359 reads (45%) | catalogued as rs1398453914; called by muse, mutect2, varscan2
- CRMP1 | chr4:5892806 A>T | 5'Flank (SNP) | VAF 66/212 reads (31%) | called by muse, mutect2, varscan2
- CSF1R | c.1754-19G>A | Intron (SNP) | VAF 197/382 reads (52%) | called by muse, mutect2, varscan2
- CYB5RL | c.541-716G>A | Intron (SNP) | VAF 158/324 reads (49%) | catalogued as COSV55277310; called by muse, mutect2, varscan2
- DNM2 | c.1336-48C>T | Intron (SNP) | VAF 185/185 reads (100%) | catalogued as rs773004268; called by muse, mutect2, varscan2
- EFEMP2 | c.-7-14C>T | Intron (SNP) | VAF 154/236 reads (65%) | called by muse, mutect2, varscan2
- EIF3F | chr11:7987324 C>T | 5'Flank (SNP) | VAF 114/183 reads (62%) | catalogued as rs768898165, COSV100562560; called by muse, varscan2
- FAM131B | c.91-145C>T | Intron (SNP) | VAF 161/472 reads (34%) | catalogued as rs748160373; called by muse, mutect2, varscan2
- FKBP6 | c.-143C>T | 5'UTR (SNP) | VAF 162/606 reads (27%) | catalogued as rs1245648456, COSV52720398; called by muse, mutect2, varscan2
- HBD | c.*45C>T | 3'UTR (SNP) | VAF 263/389 reads (68%) | catalogued as rs1320721138; called by muse, mutect2, varscan2
- IQUB | c.1759-1185C>T | Intron (SNP) | VAF 68/130 reads (52%) | catalogued as rs1453452560; called by muse, mutect2
- KATNIP | c.-9C>T | 5'UTR (SNP) | VAF 162/303 reads (53%) | called by muse, mutect2, varscan2
- KATNIP | c.-8C>T | 5'UTR (SNP) | VAF 163/304 reads (54%) | catalogued as rs1245660039; called by muse, mutect2, varscan2
- KCNA1 | c.*40C>T | 3'UTR (SNP) | VAF 66/269 reads (25%) | catalogued as rs754962797; called by muse, mutect2
- KCNAB1 | c.276-129525A>C | Intron (SNP) | VAF 195/719 reads (27%) | called by muse, mutect2, varscan2
- KYAT1 | c.-6-16A>T | Intron (SNP) | VAF 106/306 reads (35%) | called by muse, mutect2, varscan2
- LINC01193 | n.1455C>T | RNA (SNP) | VAF 179/405 reads (44%) | called by muse, mutect2, varscan2
- MAP4 | c.1999+2591C>T | Intron (SNP) | VAF 161/341 reads (47%) | called by muse, mutect2, varscan2
- MASP1 | c.1304-5422G>A | Intron (SNP) | VAF 114/342 reads (33%) | catalogued as rs1048784409; called by muse, varscan2
- MAST4 | c.674+63736G>A | Intron (SNP) | VAF 186/391 reads (48%) | called by muse, mutect2, varscan2
- MAST4 | c.674+63737G>A | Intron (SNP) | VAF 186/395 reads (47%) | called by muse, mutect2, varscan2
- MEP1A | c.70-28C>T | Intron (SNP) | VAF 41/41 reads (100%) | catalogued as rs747902979; called by muse, mutect2, varscan2
- MFRP | chr11:119344381 C>G | 5'Flank (SNP) | VAF 467/468 reads (100%) | catalogued as rs777996384; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MIR9-1HG | n.617C>T | RNA (SNP) | VAF 184/404 reads (46%) | called by muse, mutect2, varscan2
- MIR9-2 | n.82C>T | RNA (SNP) | VAF 238/523 reads (46%) | called by muse, mutect2, varscan2
- MMP26 | c.*31C>T | 3'UTR (SNP) | VAF 25/78 reads (32%) | called by muse, mutect2, varscan2
- NACA | c.70+4715C>G | Intron (SNP) | VAF 75/265 reads (28%) | catalogued as COSV100771049; called by muse, mutect2, varscan2
- NME9 | c.91+331G>A | Intron (SNP) | VAF 150/302 reads (50%) | called by muse, mutect2, varscan2
- PDLIM2 | c.-250C>T | 5'UTR (SNP) | VAF 203/427 reads (48%) | called by muse, mutect2, varscan2
- PDLIM7 | c.573-98C>T | Intron (SNP) | VAF 316/696 reads (45%) | catalogued as rs1362511325; called by muse, mutect2, varscan2
- PLOD1 | c.*20T>C | 3'UTR (SNP) | VAF 429/990 reads (43%) | called by muse, mutect2, varscan2
- PPFIBP2 | c.*380G>A | 3'UTR (SNP) | VAF 114/367 reads (31%) | called by muse, mutect2, varscan2
- RAD51C | c.705+3219C>T | Intron (SNP) | VAF 47/48 reads (98%) | called by muse, mutect2, varscan2
- RALYL | c.-16G>A | 5'UTR (SNP) | VAF 73/164 reads (45%) | called by muse, mutect2
- REG3A | c.*10G>A | 3'UTR (SNP) | VAF 106/239 reads (44%) | catalogued as rs756354351, COSV100532491; called by muse, mutect2, varscan2
- RGS11 | c.319-15C>T | Intron (SNP) | VAF 214/491 reads (44%) | called by muse, mutect2, varscan2
- RGS11 | c.319-16C>T | Intron (SNP) | VAF 213/485 reads (44%) | called by muse, mutect2, varscan2
- RNU1-6P | chr1:16535970 T>C | 5'Flank (SNP) | VAF 420/2149 reads (20%) | called by muse, mutect2, varscan2
- RNU6-713P | chr12:40550113 A>G | 3'Flank (SNP) | VAF 57/168 reads (34%) | called by muse, mutect2, varscan2
- RPH3A | c.71+3413G>T | Intron (SNP) | VAF 59/208 reads (28%) | catalogued as rs1455521980; called by muse, mutect2
- RPL11 | c.6+10T>C | Intron (SNP) | VAF 150/826 reads (18%) | called by muse, mutect2, varscan2
- RPL31 | c.*5C>T | 3'UTR (SNP) | VAF 24/92 reads (26%) | called by muse, mutect2, varscan2
- RPL31 | c.*6C>T | 3'UTR (SNP) | VAF 24/91 reads (26%) | catalogued as rs1054748125, COSV65215145; called by muse, mutect2, varscan2
- SALL2 | c.-2G>A | 5'UTR (SNP) | VAF 109/303 reads (36%) | called by muse, mutect2, varscan2
- SH2D3C | c.516-758G>A | Intron (SNP) | VAF 97/265 reads (37%) | catalogued as rs548514227; called by muse, mutect2, varscan2
- SLC24A2 | c.-16C>T | 5'UTR (SNP) | VAF 25/49 reads (51%) | catalogued as rs372514160, COSV99647573; called by muse, mutect2, varscan2
- SLC24A2 | c.-17C>T | 5'UTR (SNP) | VAF 25/49 reads (51%) | called by muse, mutect2, varscan2
- SLC36A2 | c.1180+47G>A | Intron (SNP) | VAF 178/391 reads (46%) | called by muse, mutect2, varscan2
- TBC1D8 | c.2476-1139C>T | Intron (SNP) | VAF 12/52 reads (23%) | catalogued as rs950521765; called by muse, mutect2, varscan2
- TEDC2 | chr16:2460094 G>A | 5'Flank (SNP) | VAF 53/110 reads (48%) | catalogued as rs1026226164; called by muse, mutect2, varscan2
- TEDC2 | chr16:2460095 G>A | 5'Flank (SNP) | VAF 53/108 reads (49%) | catalogued as rs1190598082; called by muse, mutect2, varscan2
- TMEM273 | c.43+10081G>A | Intron (SNP) | VAF 155/155 reads (100%) | called by muse, mutect2, varscan2
- TUBB8P7 | n.1532C>T | RNA (SNP) | VAF 422/632 reads (67%) | called by mutect2, varscan2
- UNC13C | c.4933+1929C>T | Intron (SNP) | VAF 154/155 reads (99%) | called by muse, mutect2, varscan2
- VPS29 | c.3+418G>A | Intron (SNP) | VAF 301/463 reads (65%) | called by muse, mutect2, varscan2
- WNK1 | c.2140-2606C>T | Intron (SNP) | VAF 91/164 reads (55%) | called by muse, mutect2, varscan2
- XIAP | c.*5798del | 3'UTR (DEL) | VAF 44/44 reads (100%) | called by mutect2, pindel*, varscan2
6 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 6 other) are not listed here.
